Gene-level copy-number profile of tumor specimen TCGA-20-1684-01A from TCGA case TCGA-20-1684, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.3 years (18,755 days).
Specimen TCGA-20-1684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5494acf1-6054-4d4f-8f5e-d39c5e9eafa4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-20-1684-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8639bc9f-d923-4cbb-9439-87ee70e0b4e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,301; copy number 2: 23,384; copy number 3: 20,673; copy number 4: 8,626; copy number 5: 3,817; copy number 6: 458; copy number 7: 343; copy number 8: 69; copy number 9: 34; copy number 10: 4; copy number 11: 14; copy number 16: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-20-1684-01A-01D-0559-01): tumor purity 0.96, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,810 genes in 97 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–4,019,508, 208 genes, copy number 5 (broad region; genes not listed).
- chr1:9,728,926–13,555,694, 151 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:38,754,216–42,473,385, 114 genes, copy number 5–6 (broad region; genes not listed).
- chr1:157,513,377–160,186,980, 106 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:185,734,391–188,732,208, 31 genes, copy number 5 (within-gene range 4–5): HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1.
- chr1:201,688,259–202,889,149, 46 genes, copy number 5 (within-gene range 4–5): IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2, SNORA70, SYT2, AC104463.2, AC104463.1, KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6, MGAT4EP, TUBA5P, ACTG1P25, RABIF.
- chr1:203,318,996–208,736,286, 156 genes, copy number 5 (broad region; genes not listed).
- chr1:228,555,793–248,919,946, 485 genes, copy number 5–8 (broad region; genes not listed).
- chr2:95,165,432–98,398,601, 115 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:221,162,771–224,585,397, 47 genes, copy number 5: AC011233.1, AC011233.2, EPHA4, TMEM256P2, AC079834.1, RPL23P5, AC068489.1, LLPHP3, HSPA9P1, RPL23AP28, PAX3, CCDC140, AC010980.1, CT75, Y_RNA, SGPP2, NANOGP2, RNU6-619P, GAPDHP49, FARSB, MOGAT1, RRAS2P2, AC104772.1, RPL31P17, ACSL3, ATG12P2, ACSL3-AS1, AC013476.1, KCNE4, RN7SL807P, HIGD1AP4, AC013448.1, AC013448.2, SCG2, MLXP1, AP1S3, AC093884.1, WDFY1, MRPL44, AC073641.1, SERPINE2, USP21P1, AC008072.1, FAM124B, AC073052.1, CUL3, ANKRD49P1.
- chr3:51,894,876–55,074,557, 93 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:105,366,909–108,378,285, 38 genes, copy number 5–8: ALCAM, CBLB, AC131237.1, AC079382.1, AC079382.2, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17.
- chr3:150,039,214–153,377,562, 64 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:168,902,194–182,035,644, 207 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr4:1,871,393–3,768,526, 51 genes, copy number 5 (within-gene range 3–5): NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99, RNF4, AL645924.1, AL645924.2, FAM193A, CR545473.1, Y_RNA, TNIP2, SH3BP2, ADD1, AL121750.1, MFSD10, NOP14-AS1, NOP14, GRK4, HTT, RNU6-204P, HTT-AS, AL390065.2, AL390065.1, MSANTD1, RGS12, AL645949.1, AL645949.2, HGFAC, AL590235.2, DOK7, LRPAP1, AL590235.1, LINC00955, AL121796.1, LINC02171, LINC02600, ADRA2C.
- chr4:13,654,374–18,021,876, 60 genes, copy number 5–7 (within-gene range 3–7): LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170, C1QTNF7, AC099550.1, CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1, CD38, HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1, LDB2, AC104656.1, AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63.
- chr5:41,306,952–43,886,628, 57 genes, copy number 5: PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1.
- chr6:33,004,182–34,426,071, 72 genes, copy number 5–6 (broad region; genes not listed).
- chr6:52,576,787–57,646,850, 92 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:122,711,887–127,519,001, 47 genes, copy number 5–7 (within-gene range 3–7): AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2.
- chr6:128,500,527–133,892,802, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:78,939,850–82,443,777, 35 genes, copy number 5 (within-gene range 4–5): MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1.
- chr7:118,880,103–123,230,741, 45 genes, copy number 5–6: GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1.
- chr8:4,496,392–7,475,082, 78 genes, copy number 5–7 (broad region; genes not listed).
- chr8:105,142,860–145,066,685, 587 genes, copy number 5–11 (broad region; genes not listed).
- chr10:110,644,336–114,996,593, 75 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:46,617,527–49,434,438, 102 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:76,349,956–78,188,626, 53 genes, copy number 5–6 (within-gene range 4–6): THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21.
- chr11:79,092,848–83,423,516, 51 genes, copy number 5–6: AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:86,441,108–92,161,889, 124 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:102,766,801–107,316,271, 66 genes, copy number 5 (broad region; genes not listed).
- chr12:9,594,551–10,329,608, 35 genes, copy number 5 (within-gene range 4–5): KLRB1, RNU6-700P, GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1, CD69, GCNAP1, KLRF1, CLEC2B, AC091814.1, KLRF2, CLEC2A, LINC02470, CLEC12A-AS1, CLEC12A, CLEC1B, CLEC12B, AC024224.2, CLEC9A, AC024224.1, CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1.
- chr14:48,489,883–51,096,061, 71 genes, copy number 5 (broad region; genes not listed).
- chr16:21,597,218–22,437,165, 30 genes, copy number 5 (within-gene range 3–5): METTL9, AC005632.3, IGSF6, RNU6-1005P, RNU6-196P, OTOA, AC092375.2, RRN3P1, AC092375.3, NPIPB4, SMG1P4, AC092375.1, AC092119.2, UQCRC2, PDZD9, AC092119.1, AC092119.3, MOSMO, AC009019.1, VWA3A, SDR42E2, AC009019.2, EEF2K, AC009034.1, POLR3E, AC092338.3, CDR2, AC092338.1, AC092338.2, MFSD13B.
- chr16:75,412,684–79,620,110, 89 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr16:80,040,662–82,192,790, 53 genes, copy number 5: AC092130.1, AC022166.1, AC105411.1, AC022166.2, DYNLRB2, AC108097.1, LINC01227, CDYL2, AC092332.1, AC099313.1, ARLNC1, AC009070.1, CMC2, AC092718.7, CENPN, AC092718.2, AC092718.8, AC092718.4, ATMIN, C16orf46, AC092718.3, AC092718.5, AC092718.6, AC092718.1, GCSH, PKD1L2, RNU6-1191P, AC092718.9, BCO1, AC131888.1, AC009148.1, GAN, MIR4720, CMIP, AC092139.1, PPIAP51, AC092139.2, MIR7854, MIR6504, AC092135.2, AC092135.1, AC092135.3, AC099524.1, PLCG2, RN7SKP176, AC092142.2, SDR42E1, HSD17B2, AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1, RN7SKP190.
- chr16:83,899,115–86,036,419, 73 genes, copy number 5–6 (broad region; genes not listed).
- chr19:14,213,052–18,151,692, 215 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr19:27,638,483–31,466,431, 76 genes, copy number 16 (broad region; genes not listed).
- chr20:30,484,925–34,347,785, 125 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
